Somatic mutation profile of tumor specimen a42f5b74-1bab-41cd-b5f7-0182fa (aliquot a42f5b74-1bab-41cd-b5f7-0182fa_D6) from CPTAC case 01OV010, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC.
Specimen a42f5b74-1bab-41cd-b5f7-0182fa: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82696ddc-5947-4411-a9e9-917c1c3c64de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ada95f64-bd0f-40be-b5ef-f2f483 (Blood Derived Normal), aliquot ada95f64-bd0f-40be-b5ef-f2f483_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c54289de-2809-41ab-a34e-247c8fffb742

The open-access MAF lists 84 somatic variants for this specimen: 57 protein-altering or splice-affecting, 16 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 16, Nonsense Mutation 5, Intron 3, 3'UTR 3, 5'UTR 3, RNA 2, Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 105/152 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BPIFB1 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 90/208 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1050317525; called by muse, mutect2, varscan2
- C22orf15 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs374808343; called by muse, mutect2, varscan2
- CDK5RAP1 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781287486; called by muse, mutect2
- CFAP45 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 121/520 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs771767770, COSV63648535; called by muse, mutect2, varscan2
- DNAJB6 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1443321248; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EXOC3L2 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368887693; called by muse, mutect2, varscan2
- EXT2 | c.197T>C p.V66A (on ENST00000343631; = p.V99A on NM_000401.3) | Missense Mutation (SNP) | VAF 54/577 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as CX099429; called by muse, mutect2, varscan2
- FGF3 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.119); catalogued as rs1221660991; called by muse, mutect2, varscan2
- GLB1L3 | c.918G>T p.W306C | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs761361083; called by muse, mutect2, varscan2
- GSDMD | c.1151C>T p.T384M | Missense Mutation (SNP) | VAF 71/273 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs371816989; called by muse, mutect2, varscan2
- JAKMIP1 | c.585C>A p.H195Q | Missense Mutation (SNP) | VAF 59/88 reads (67%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV99288692; called by muse, mutect2, varscan2
- KIF2C | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | catalogued as COSV100945689; called by muse, mutect2, varscan2
- MCM3AP | c.5737C>T p.H1913Y | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs763339483; called by muse, mutect2, varscan2
- NAPSA | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs748819177; called by muse, mutect2, varscan2
- PSD2 | c.1453T>C p.F485L | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1317636372; called by muse, mutect2, varscan2
- SLC24A4 | c.1315G>A p.V439I | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs371005554; called by muse, mutect2, varscan2
- SLC39A12 | c.595G>T p.G199C | Missense Mutation (SNP) | VAF 73/151 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101069840, COSV101070119; called by muse, mutect2, varscan2
- SYNM | c.4628C>G p.S1543* (on ENST00000336292 / NM_145728.3; = p.S1231* on NM_015286.6) | Nonsense Mutation (SNP) | VAF 32/149 reads (21%) | catalogued as COSV50444263; called by muse, mutect2, varscan2
- TRPV5 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 27/100 reads (27%) | catalogued as COSV54683748; called by muse, mutect2, varscan2
- AC134980.2 | c.530T>C p.F177S | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- ADGRG4 | c.8488G>T p.E2830* | Nonsense Mutation (SNP) | VAF 89/414 reads (21%) | called by muse, mutect2, varscan2
- AGBL1 | c.883C>G p.P295A | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- ALAS1 | c.1860dup p.M621Dfs*3 | Frame Shift Ins (INS) | VAF 78/246 reads (32%) | called by pindel, varscan2
- ALG8 | c.497A>G p.N166S | Missense Mutation (SNP) | VAF 106/297 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- BMT2 | c.380C>A p.T127N | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1orf94 | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 69/255 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CYP51A1 | c.1283A>T p.N428I | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2
- DENND2B | c.2684T>C p.L895P | Missense Mutation (SNP) | VAF 79/142 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- DUSP8 | c.1711A>T p.T571S | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EDC3 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- EGF | c.1316G>A p.C439Y | Missense Mutation (SNP) | VAF 105/162 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FANCD2 | c.2243A>T p.N748I | Missense Mutation (SNP) | VAF 148/376 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by mutect2, varscan2
- HEPACAM | c.1141G>T p.A381S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- KANK4 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 75/296 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- KCNAB1 | c.1149T>G p.I383M (on ENST00000490337 / NM_172160.3; = p.I372M on NM_003471.3) | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- METAP2 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- MGAM2 | c.4912G>T p.D1638Y | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MUC16 | c.28640C>G p.S9547C | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- NID2 | c.3010C>T p.H1004Y | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- OR5D13 | c.841A>C p.T281P | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PDXDC1 | c.674T>C p.I225T | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- PGM3 | c.1604G>A p.G535E | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXNB2 | c.5412+1G>T p.X1804_splice | Splice Site (SNP) | VAF 88/110 reads (80%) | called by muse, varscan2
- PRPS2 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- PRR19 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAD51D | c.647T>C p.L216P | Missense Mutation (SNP) | VAF 182/259 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASSF7 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- REST | c.3137dup p.N1046Kfs*12 | Frame Shift Ins (INS) | VAF 80/141 reads (57%) | called by mutect2, pindel, varscan2
- SLC19A3 | c.1021T>A p.W341R | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SUDS3 | c.574C>G p.P192A | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TARS3 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- TMEM132E | c.1048G>A p.A350T (on ENST00000321639; = p.A440T on NM_001304438.2) | Missense Mutation (SNP) | VAF 53/83 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- UPF2 | c.3334G>A p.D1112N | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- WNT5A | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF311 | c.1883G>A p.G628E | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZPLD1 | c.1220A>G p.N407S (on ENST00000466937 / NM_001329788.1; = p.N423S on NM_175056.2) | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABTB2 | c.771C>T p.A257= | Silent (SNP) | VAF 60/304 reads (20%) | called by muse, mutect2
- ADGRG4 | c.5688C>A p.S1896= | Silent (SNP) | VAF 36/164 reads (22%) | called by mutect2, varscan2
- ALDH6A1 | c.1554A>G p.E518= | Silent (SNP) | VAF 120/200 reads (60%) | called by muse, mutect2, varscan2
- BSN | c.5079G>A p.A1693= | Silent (SNP) | VAF 77/161 reads (48%) | catalogued as rs765841525, COSV56525614; called by muse, mutect2, varscan2
- CLPX | c.912A>G p.Q304= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100269332; called by muse, mutect2, varscan2
- CNTRL | c.4056G>A p.S1352= | Silent (SNP) | VAF 148/192 reads (77%) | catalogued as rs370206855; called by muse, mutect2, varscan2
- COL6A6 | c.420A>G p.S140= | Silent (SNP) | VAF 112/278 reads (40%) | called by muse, mutect2, varscan2
- H2BC4 | c.15C>T p.A5= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as rs368610585, COSV58416792; called by muse, mutect2, varscan2
- HNRNPU | c.1464T>C p.I488= (on ENST00000283179; = p.I550= on NM_004501.3) | Silent (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- INSC | c.831C>A p.A277= | Silent (SNP) | VAF 20/109 reads (18%) | called by muse, mutect2, varscan2
- MTG1 | c.906C>G p.A302= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV58152826; called by muse, mutect2, varscan2
- PPP1R16A | c.507C>T p.D169= | Silent (SNP) | VAF 37/219 reads (17%) | catalogued as rs199905128; called by muse, mutect2, varscan2
- SALL4 | c.2385C>T p.A795= | Silent (SNP) | VAF 115/309 reads (37%) | catalogued as rs142446452; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN9A | c.4677T>G p.T1559= (on ENST00000303354; = p.T1548= on NM_002977.3) | Silent (SNP) | VAF 101/223 reads (45%) | called by muse, mutect2, varscan2
- SLC5A6 | c.186G>A p.A62= | Silent (SNP) | VAF 83/166 reads (50%) | catalogued as rs756953991, COSV60160726; called by muse, mutect2, varscan2
- TRIM35 | c.1440C>A p.I480= | Silent (SNP) | VAF 47/64 reads (73%) | called by muse, mutect2, varscan2
- AC007557.3 | n.2328T>A | RNA (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- AK2 | c.*1300C>G | 3'UTR (SNP) | VAF 121/466 reads (26%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*3367C>T | 3'UTR (SNP) | VAF 39/181 reads (22%) | called by muse, mutect2, varscan2
- CYP27B1 | c.-5A>T | 5'UTR (SNP) | VAF 66/129 reads (51%) | catalogued as rs775231921; called by muse, mutect2, varscan2
- HERC2P2 | n.2749G>A | RNA (SNP) | VAF 30/54 reads (56%) | catalogued as rs780936779; called by muse, mutect2, varscan2
- PHF21B | c.-2G>T | 5'UTR (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- TM6SF2 | c.401+52C>T | Intron (SNP) | VAF 34/206 reads (17%) | called by muse, mutect2, varscan2
- TMEM234 | c.329-152G>A | Intron (SNP) | VAF 63/173 reads (36%) | called by muse, mutect2, varscan2
- VWDE | c.-10G>A | 5'UTR (SNP) | VAF 18/148 reads (12%) | catalogued as rs1212866597; called by muse, mutect2, varscan2
- WIPI1 | c.1293+1563C>T | Intron (SNP) | VAF 34/56 reads (61%) | called by muse, mutect2, varscan2
- XCL1 | c.*2A>T | 3'UTR (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
